MMRF case MMRF_1180 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/742dda13-fd92-4b91-9832-9dfbbe94bd5c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 914 days (2.5 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.1 years (23,040 days); ISS stage: III; Days to last known disease status: 914 days (2.5 years); Days to last follow up: 914 days (2.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 539 days (1.5 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 194 days; Days to treatment end: 194 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 196 days; Days to treatment end: 196 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 914.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4236 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 3.17 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 7.83 µg/mL; Hemoglobin 6.51 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 211 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.53 mmol/L; Albumin 49 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 91 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.4 mg/dL; Immunoglobulin G 3.27 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.03 g/L; Beta 2 Microglobulin 5.27 µg/mL; Hemoglobin 5.83 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.45 mmol/L; Albumin 49 g/L; Total Protein 6.9 g/dL; Glucose 4.95 mmol/L.
- Day 183: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 3.82 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.01 g/L; Beta 2 Microglobulin 5.91 µg/mL; Lactate Dehydrogenase 9.69 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 161 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.56 mmol/L.
- Day 261 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Beta 2 Microglobulin 5.23 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 210 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.34 mmol/L.
- Day 357 (ECOG 1): M Protein 0.4 g/dL; Immunoglobulin G 8.16 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.93 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 140 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.55 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 4.46 mmol/L.
- Day 469 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.87 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 1.24 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 40 ×10⁹/L; Creatinine 165 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 5.83 mmol/L.
- Day 567 (ECOG 0): Hemoglobin 6.32 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 179 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 4.68 mmol/L.
- Day 651 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.23 mg/dL; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.59 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 187 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.5 mmol/L; Albumin 50 g/L; Total Protein 7.8 g/dL; Glucose 7.21 mmol/L.
- Day 749 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 8.04 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 5.79 µg/mL; Lactate Dehydrogenase 9.45 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 232 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.45 mmol/L; Albumin 49 g/L; Total Protein 7.3 g/dL; Glucose 4.68 mmol/L.
- Day 798 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 8.25 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.59 g/L; Beta 2 Microglobulin 6.48 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.45 mmol/L; Albumin 49 g/L; Total Protein 7.7 g/dL; Glucose 4.68 mmol/L.
- Day 903 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.48 mg/dL; Immunoglobulin G 8.31 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 8.47 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 190 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day -6: Weight: 53 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1180_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1180_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
